Gene-level copy-number profile of tumor specimen TCGA-VQ-A8E3-01A from TCGA case TCGA-VQ-A8E3, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 79.2 years (28,919 days).
Specimen TCGA-VQ-A8E3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.c55553f3-3d89-4926-abb3-538a92f05f68.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8E3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/81a5ff3d-f84e-43f8-bc70-a182faa85a40

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 115; copy number 1: 8,176; copy number 2: 31,431; copy number 3: 14,895; copy number 4: 4,017; copy number 5: 945; copy number 6: 227; copy number 8: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8E3-01A-11D-A396-01): tumor purity 0.6, ploidy 2.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 114 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:9,771,153–10,054,936, 1 gene (within-gene range 0–1): SLC2A9.
- chr4:9,922,814–10,295,579, 16 genes: AC108199.1, SLC2A9-AS1, AC005674.1, WDR1, MIR3138, RNA5SP155, AC093664.1, AC006499.6, AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.
- chr4:77,157,207–78,544,269, 18 genes (within-gene range 0–1): CCNG2, AC008638.3, AC008638.2, AC008638.1, AC092674.1, CXCL13, AC104701.1, CNOT6L, MRPL1, AC112225.1, AC114801.2, HMGB1P44, HNRNPA1P56, AC114801.1, AC114801.3, FRAS1, SERBP1P5, MICOS10P4.
- chr4:87,386,883–88,331,421, 27 genes: RN7SL681P, AC112250.1, NUDT9, AC112250.2, SPARCL1, AC093895.1, DSPP, DMP1, Y_RNA, CHCHD2P7, IBSP, MEPE, HSP90AB3P, AC131944.1, SPP1, RNU1-36P, PKD2, ABCG2, AC097484.1, RNU6-818P, RNU6ATAC31P, AC097484.2, RNU6-1298P, PPM1K, RNU6-112P, PPM1K-DT, Y_RNA.
- chr4:164,933,086–166,104,457, 29 genes (within-gene range 0–1): AC106872.10, AC106872.5, NACA3P, AC106872.1, TRIM61, FAM218A, AC106872.4, AC106872.9, AC106872.8, AC106872.2, TRIM60, AC106872.11, AC106872.7, AC106872.6, TRIM75P, TMEM192, KLHL2, RNU4-87P, GK3P, MSMO1, CPE, MIR578, HADHAP1, SCGB1D5P, NOL8P1, AC080079.2, AC080079.1, LINC01179, TLL1.
- chr18:37,243,040–37,762,131, 8 genes: CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1, MIR4318, RPL12P40.
- chr18:57,961,231–58,629,091, 15 genes (within-gene range 0–1): LINC01897, HMGN1P30, NEDD4L, AC107896.1, AC090236.2, AC090236.1, AC105105.2, MIR122HG, MIR122, MIR3591, AC105105.4, ALPK2, AC105105.3, AC105105.1, AC104971.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,177 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:197,737,179–198,222,513, 18 genes, copy number 5: FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr7:70,972–176,013, 7 genes, copy number 5: AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2.
- chr7:7,356,203–9,189,857, 26 genes, copy number 5 (within-gene range 4–5): COL28A1, AC004982.1, AC004982.2, MIOS, AC004948.1, RPA3, UMAD1, AC007161.3, AC007161.2, AC007161.1, RNU6-534P, CCNB2P1, AC006042.3, GLCCI1-DT, GLCCI1, AC006042.2, ICA1, AC006042.1, AC007009.1, AC007128.1, AC007128.2, NXPH1, AC009500.1, AC004852.2, AC004852.1, AC004852.3.
- chr7:80,742,538–85,489,293, 33 genes, copy number 5 (within-gene range 4–5): SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972.
- chr10:44,712–744,958, 14 genes, copy number 5: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1.
- chr10:5,684,838–10,462,361, 75 genes, copy number 5 (broad region; genes not listed).
- chr18:7,566,782–9,862,551, 51 genes, copy number 5 (within-gene range 4–5): PTPRM, AP000897.2, AP000897.1, U3, AP005900.1, AC006566.2, AC006566.1, AP001094.3, AP001094.2, AP001094.1, COP1P1, RN7SL50P, THEMIS3P, AKR1B1P6, RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, AP001531.1, AP005899.2, RPS4XP19, NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1, ANKRD12, Y_RNA, Y_RNA, AP001033.2, AP001033.1, TWSG1, AP001033.3, AP005432.2, RALBP1, AP005432.1, RNU2-27P, PPP4R1, AP001381.1, PPP4R1-AS1, RNU6-903P, LINC02856, KRT18P8, RAB31, AP000902.1, ZNF415P1, RN7SL862P, AC006238.2, RNA5SP449.
- chr19:6,531,026–15,911,824, 523 genes, copy number 5–6 (broad region; genes not listed).
- chr19:57,119,138–57,359,898, 18 genes, copy number 6 (within-gene range 3–6): USP29, ZIM3, AC025588.2, AC025588.3, DUXA, AC025588.1, ZNF264, AURKC, ZNF805, AC005261.3, ZNF460-AS1, ZNF460, AC005261.5, AC005261.1, AC005261.4, ZNF543, AC005261.2, ZNF304.
- chr20:87,250–12,381,255, 265 genes, copy number 5–8 (broad region; genes not listed).
- chr20:13,389,392–13,638,932, 1 gene, copy number 5 (within-gene range 4–5): TASP1.
- chr20:13,714,322–22,074,654, 146 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,790. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
